Somatic mutation profile of tumor specimen MP2PRT-PARTRW-TBP1-A (aliquot MP2PRT-PARTRW-TBP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PARTRW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,062 days).
Specimen MP2PRT-PARTRW-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6352ec71-a5f6-49e8-bfff-d6ca6e1054e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTRW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTRW-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6da02c1b-a128-4316-b184-8b20ef574478

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP6 | c.4995G>T p.K1665N | Missense Mutation (SNP) | VAF 103/270 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV99028585, COSV99804084; called by muse, mutect2, varscan2
- ALOX5 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.052); catalogued as rs763416007; called by muse, mutect2
- ATXN7 | c.2344G>A p.G782R | Missense Mutation (SNP) | VAF 183/342 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs148498434; called by muse, mutect2, varscan2
- DPP10 | c.2350G>T p.E784* | Nonsense Mutation (SNP) | VAF 119/229 reads (52%) | catalogued as COSV59666352, COSV59673998, COSV59676988; called by muse, mutect2, varscan2
- F5 | c.6322C>T p.R2108C | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200646894; called by muse, mutect2, varscan2
- KDM6A | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 176/184 reads (96%) | catalogued as rs189751539, CM146948, COSV65037198; called by muse, mutect2, varscan2
- DDX41 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 76/177 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- EYS | c.2289G>T p.W763C | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- HERC1 | c.14519T>G p.I4840S | Missense Mutation (SNP) | VAF 112/256 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIAA1210 | c.3858C>A p.S1286R | Missense Mutation (SNP) | VAF 136/320 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- SFRP4 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- TFAP4 | c.63_64del p.K22Rfs*8 | Frame Shift Del (DEL) | VAF 108/286 reads (38%) | called by pindel, varscan2
- MAGEC2 | c.210G>A p.E70= | Silent (SNP) | VAF 294/301 reads (98%) | called by muse, mutect2, varscan2
- PCDH12 | c.1587C>T p.A529= | Silent (SNP) | VAF 148/336 reads (44%) | catalogued as rs534866419, COSV51524720; called by muse, mutect2, varscan2
- STAU2 | c.1605A>G p.K535= | Silent (SNP) | VAF 6/137 reads (4%) | called by muse, mutect2
